Gene-level copy-number profile of tumor specimen TCGA-AB-2938-03A from TCGA case TCGA-AB-2938, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute megakaryoblastic leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.3 years (27,881 days).
Specimen TCGA-AB-2938-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.bc7a1f2a-e1b0-4a7e-bc8d-f3cd7d4b3a46.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2938-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b70e843-ea25-4dc0-9529-cf4eba90d847

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,385; copy number 2: 51,628; copy number 3: 1,184; copy number 4: 545; copy number 5: 348; copy number 6: 540; copy number 7: 138; copy number 8: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AB-2938-03A-01D-0756-21): tumor purity 0.59, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,076 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:7,380,534–10,373,130, 135 genes, copy number 5 (broad region; genes not listed).
- chr17:10,390,322–10,421,950, 1 gene, copy number 5: MYH8.
- chr19:4,043,303–5,624,046, 61 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr19:6,661,253–11,619,161, 265 genes, copy number 5–7 (broad region; genes not listed).
- chr19:11,648,364–11,652,877, 1 gene, copy number 6: ZNF887P.
- chr20:59,460,619–64,313,132, 165 genes, copy number 6 (broad region; genes not listed).
- chr21:10,328,411–17,633,199, 111 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:25,169,431–27,675,024, 40 genes, copy number 5 (within-gene range 2–5): AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673.
- chr21:36,698,773–46,665,124, 297 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,004. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
